Somatic mutation profile of tumor specimen 0DWYWV from CCDI case PBCPWC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 6.1 years (2,213 days).
Specimen 0DWYWV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7d3847c-aa65-4981-819c-b9f193c2178b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/062821ad-9bdb-4991-b801-287011199b94

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANXA11 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368132715; called by muse, varscan2
- IL21R | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs372897692; ClinVar: uncertain significance; called by muse, varscan2
- PCARE | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs202166083, COSV59053622; called by muse, varscan2
- METTL17 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, varscan2
- TAZ | c.371-13C>T | Intron (SNP) | VAF 42/204 reads (21%) | called by muse, varscan2
